Surgical pathology report (de-identified scan), TCGA case TCGA-V1-A9OL, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of California San Francisco, specimen TCGA-V1-A9OL-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS

- A. Seminal vesicle fat, biopsy: Vascular fibroadipose tissue, no tumor.
- B. Lymph nodes, right pelvic, dissection: No tumor in three lymph nodes (0/3).
- C. Lymph nodes, left pelvic, dissection: No tumor in six lymph nodes (0/6).
- D. Prostate and seminal vesicles, radical prostatectomy:
- 1. Prostatic adenocarcinoma, Gleason grade 5+4, score=9, with extraprostatic extension, margins negative; see comment.
- 2. Left and right seminal vesicles involved by prostatic adenocarcinoma.

COMMENT:

Synoptic Comment for Prostate Tumors

- **Type of tumor:** Small acinar adenocarcinoma.
- **Location of tumor:** Left posterior mid gland, slides D9-D11; right posterior mid gland, slides D6-D8; right anterior apex and mid gland, slides D3-D5.
- **Estimated volume of tumor:** 2 cm³.
- **Gleason score:** 5+4; primary pattern 5, secondary pattern 4.
- **Estimated volume > Gleason pattern 3:** 100%.
- **Involvement of capsule:** Tumor invades capsule in slides D7 and D8.
- **Extraprostatic extension:** Present to a limited extent in slides D7, D8, D17, and D18.
- **Margin status for tumor:**
- Negative.
- **Margin status for benign prostate glands:**
- Benign glands present at inked excision margins; slide D2.
- **High-grade prostatic intraepithelial neoplasia (HGPIN):** None.
- **Tumor involvement of seminal vesicle:** Bilateral (slides D17 and D18).
- **Perineural infiltration:** Present (slide D3).
- **Lymphovascular infiltration:** Present (slide D17).

IED-0-3
Adenocarcinoma NOS
8140/3
Site: Prostate NOS
C61.9
7/27/14

[page 2 of 3]
- Lymph node status:

- Negative; total number of nodes examined: 9.

- AJCC/UICC stage: pT3bN0MX.

Specimen(s) Received

A: Seminal vesicle fat

B: Right pelvic lymph nodes

C: Left pelvic lymph nodes

D: Prostate & seminal vesicles (fresh)

Clinical History

The patient is a [REDACTED] man with a preoperative diagnosis, per the electronic medical record of prostatic adenocarcinoma Gleason 5+4=9.

Gross Description

The specimen is received in four parts, each labeled with the patient's name and unit number.

Part A, additionally labeled "1 - seminal vesicle fat," consists of one, soft, yellow, irregular, unoriented adipose tissue fragment (1.6 x 1.3 x 0.3 cm). The specimen is entirely submitted intact in cassette A1.

Part B, additionally labeled "2 - right pelvic lymph nodes," consists of multiple, soft, yellow-brown, irregular, unoriented, fibroadipose tissue fragments (5 x 3 x 1 cm in aggregate). Three pink-tan lymph node candidates are identified (0.3 to 2 cm in greatest diameter). Representative sections are submitted as follows:

Cassette B1: Intact lymph node candidates.

Cassette B2: Single bisected lymph node candidate.

Part C, additionally labeled "3 - left pelvic lymph nodes," consists of multiple, soft, yellow-brown, irregular, unoriented fibroadipose tissue fragments (4.7 x 2 x 0.6 cm in aggregate). Multiple pink-tan lymph node candidates are identified (0.6 to 1.7 cm in greatest diameter). Representative sections are submitted as follows:

Cassette C1: Intact lymph node candidates.

Cassette C2: Single bisected lymph node candidate.

Part D, received fresh and labeled "prostate and seminal vesicles," consists of a prostatectomy specimen (34.5 gm; 3 cm from apex to base x 4 cm in width x 3.5 cm from anterior to posterior).

GROSS PATHOLOGIC FINDINGS: The specimen is bulging in the right mid gland. The peripheral zone has a suspicious lesion in the right aspect (2.5 x 1.8 x 1.5 cm) in slices 1-6, that abuts the capsule in slice 3. Uninvolved peripheral and central transformation zone is pink-white without obvious lesions. The anterior fibrous stroma is intact. The remaining capsule is ripped and sutured closed.

The seminal vesicle/vas deferens bundles are present (right 3 x 2.5 x 0.5 cm; left 4 x 2 x 0.5 cm).

ORIENTED BY: Anatomic landmarks; seminal vesicle and urethra.

INKING: Right anterior in green, left anterior in blue, posterior in black.

POTENTIAL STUDIES: Tissue is recovered for tissue banking by the

GROSS PHOTOGRAPHS: Yes.

TOTAL NUMBER OF SLICES: 6.

AVERAGE SLICE THICKNESS: 0.4 cm.

CASSETTES: Representative sections are submitted as follows:

Apical margins

D1: Right apex.

D2: Left apex.

[page 3 of 3]
Right anterior quadrant

D3: Slice 2.

D4: Slice 3.

D5: Slice 4.

Right posterior quadrant

D6: Slice 2.

D7: Slice 3.

D8: Slice 4.

Left posterior quadrant

D9: Slice 2.

D10: Slice 3.

D11: Slice 4.

Left anterior quadrant

D12: Slice 2.

D13: Slice 3.

D14: Slice 4.

Bladder margins

D15: Right.

D16: Left.

Prostatic/seminal vesicle junction and cross-section of vas deferens

D17: Right.

D18: Left.

The specimen is grossly reviewed by

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Electronically

Source: NCI Genomic Data Commons file 83bf912f-556e-4e5a-a28a-38d6a28751b1 (TCGA-V1-A9OL.E63E681C-8E25-4C1E-8C37-9EAA2697088B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).